Surgical pathology report (de-identified scan), TCGA case TCGA-39-5028, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5028-01A (Primary Tumor).

[page 1 of 6]
Clinical Diagnosis & History:

██████████, former smoker, with right lung nodules discovered on chest CT.
Biopsy => squamous carcinoma.

Specimens Submitted:

- 1: SP: Right level four mediastinal lymph nodes ██████████
- 2: SP: Left level four mediastinal lymph nodes ██████████
- 3: SP: Right level 4 mediastinal lymph nodes #2 ██████████
- 4: SP: Level 7 subcarinal lymph nodes ██████████
- 5: SP: Right upper lobe lung wedge ██████████
- 6: SP: Level seven subcarinal lymph nodes ██████████
- 7: SP: Right level eleven interlobar lymph nodes ██████████
- 8: SP: Right lower lobe lung ██████████

DIAGNOSIS:

- 1) LYMPH NODE, LEVEL IV, RIGHT MEDIASTINAL; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 2) LYMPH NODES, LEVEL IV, LEFT MEDIASTINAL; EXCISION:
- MULTIPLE FRAGMENTS OF BENIGN ANTHRACOTIC LYMPH NODES.
- 3) LYMPH NODES, LEVEL IV, RIGHT MEDIASTINAL #2; EXCISION:
- MULTIPLE FRAGMENTS OF BENIGN ANTHRACOTIC LYMPH NODES.
- 4) LYMPH NODE, LEVEL VII, SUBCARINAL; EXCISION:
- TWO FRAGMENTS OF BENIGN ANTHRACOTIC LYMPH NODES.
- 5) LUNG, RIGHT UPPER LOBE; WEDGE RESECTION:
- SQUAMOUS CELL CARCINOMA OF THE RIGHT UPPER LOBE, MODERATELY DIFFERENTIATED.
- THE TUMOR'S GREATEST DIAMETER IS 2.1 X 1.8 X 0.9 CM.
- NO VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE MAINSTEM BRONCHUS IS INVOLVED BY IN SITU CARCINOMA.
- THE TUMOR EXTENDS SUBPLEURALLY BUT NOT TO THE PLEURAL SURFACE.
- IN SITU CARCINOMA IS ALSO PRESENT.
- THE STAPLED MARGIN IS FREE OF TUMOR
- THE NON-NEOPLASTIC LUNG SHOWS INTERSTITIAL FIBROSIS AND FOCAL ORGANIZED PNEUMONIA.

** Continued on next page **

[page 2 of 6]
NOTE: THE TUMOR IS SIMILAR IN MORPHOLOGY TO THE TUMOR IN PART 8.

- 6) LYMPH NODES, LEVEL VII, SUBCARINAL; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 7) LYMPH NODES, LEVEL XI, RIGHT INTERLOBAR; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 8) LUNG, RIGHT, LOWER LOBE; LOBECTOMY:
- SQUAMOUS CELL CARCINOMA OF THE RIGHT LOWER LOBE, MODERATELY TO POORLY DIFFERENTIATED.
- THE TUMOR'S GREATEST DIAMETER IS 6.6 X 5.1 X 3.4 CM.
- THE MAINSTEM BRONCHUS IS INVOLVED BY INVASIVE CARCINOMA.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE STAPLED MARGIN IS FREE OF TUMOR
- THE NON-NEOPLASTIC LUNG SHOWS EMPHYSEMATOUS CHANGES, INTERSTITIAL FIBROSIS AND OSSEOUS METAPLASIA.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): PERIBRONCHIAL 3/7.
- NO DIRECT TUMOR EXTENSION INTO LYMPH NODES IS IDENTIFIED.

NOTE: WHILE THE INTERSTITIAL FIBROSIS SHOWS FOCAL HONEYCOMBING AND FIBROTIC CHANGES THAT RAISED THE POSSIBILITY OF USUAL INTERSTITIAL PNEUMONIA. THE GROSS SPECIMEN SHOWS THE FIBROTIC AREAS LOCALIZED AROUND THE TUMOR RATHER THAN DIFFUSELY FIBROTIC CHANGE. THE CASE IS ALSO REVIEWED BY [REDACTED] WHO AGREED WITH THE RENDERED INTERPRETATION.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh for intraoperative consultation, labeled "right level 4 mediastinal lymph nodes" and consists of two pink tan firm lymph nodes ranging from 0.6 x 0.3 x 0.3 cm to 0.7 x 0.4 x 0.3 cm in greatest dimension. All identified lymph nodes are examined by frozen section and entirely submitted.

Summary of sections:
FSC frozen section control

** Continued on next page **

[page 3 of 6]
2). The specimen is received fresh for intraoperative consultation, labeled "left level 4 mediastinal lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 x 0.2 x 0.2 cm to 0.5 x 0.3 x 0.3 cm in greatest dimension. All identified lymph nodes are examined by frozen section and entirely submitted.

Summary of sections:
FSC frozen section control

3). The specimen is received fresh for intraoperative consultation, labeled "right level 4 mediastinal lymph nodes #2" and consists of multiple pink tan firm lymph nodes ranging from 0.2 x 0.2 x 0.1 cm to 0.4 x 0.3 x 0.2 cm in greatest dimension. All identified lymph nodes are examined by frozen section and entirely submitted.

Summary of sections:
FSC frozen section control

4). The specimen is received fresh for frozen section consultation, labeled "Level seven subcarinal lymph nodes" and consists of two pieces of pink tan tissue measuring 0.3 x 0.3 x 0.2 cm each. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

5). The specimen is received fresh for frozen section consultation, labeled "Right upper lobe lung wedge" and consists of a lung wedge measuring 5.3 x 2.4 x 2.2 cm. The pleural surface is pink-tan and smooth, with a centrally located white tan and slightly puckered indurated area identified. Sectioning through this area reveals a 2 x 1.8 x 0.9 cm white-tan ill-defined subpleural tumor nodule, which is located 0.2 cm from the nearest stapled margin. The remainder of the lung parenchyma is red-tan and spongy with dilated areas identified. Representative sections of the nodule are submitted for frozen section consultation, for permanent section and the TPS.

Summary of sections:
FSC -- frozen section control

** Continued on next page **

[page 4 of 6]
SM stapled margin shaved
RST-representative sections tumor
Rs representative sections

6). The specimen is received in formalin, labeled "Level seven subcarinal lymph nodes" and consists of two brown tan fleshy lymph nodes measuring 2.5 and 3 cm in greatest dimension. The lymph nodes are bisected and entirely submitted.

Summary of sections:
BLN- bisected lymph nodes

7). The specimen is received in formalin, labeled "Right level 11 interlobar lymph nodes" and consists of 4 brown tan fleshy lymph nodes measuring from 0.6 to 1.2 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:
BLN- bisected lymph nodes

8). The specimen is received fresh, later placed in formalin, labeled "Right lower lobe lung" and consists of a lung lobe measuring 15 x 11.9 x 5.9 cm. A previous incision is identified at the surface measuring 6.8 cm in greatest dimension. This area has been sutured shut. The bronchial and vascular margins are identified, and appear grossly uninvolved by tumor. Upon opening, the bronchus is filled with thick red-tan mucoid material. The pleural surface is pink-tan and primarily smooth. Sectioning through the previously incised area reveals a 6.6 x 5.1 x 3.4 cm ill defined gray tan centrally located tumor mass. The mass appears 3.5 cm from the nearest stapled resection margin, 5.7 cm from the bronchial margin, and the edge of the mass abuts the pleural surface. Sectioning through the mass reveals an extensive area of subpleural dilated spaces partially surrounding the tumor.

Further sectioning shows the mass abutting the distal bronchial wall of the smaller portion of the bronchus, with partial possible obliteration of the distal bronchials noted. Sectioning through the remainder of the lung reveals extensive areas of dilated spaces, and few red tan spongy soft areas.

Summary of sections:

** Continued on next page **

[page 5 of 6]
Summary of Sections:

Part 1: SP: Right level four mediastinal lymph nodes [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		fsc	2

Part 2: SP: Left level four mediastinal lymph nodes [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		FSC	5

Part 3: SP: Right level 4 mediastinal lymph nodes #2 [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		FSC	4

Part 4: SP: Level 7 subcarinal lymph nodes [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		FSC	1

Part 5: SP: Right upper lobe lung wedge [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		fsc	1
2		rs	2
2		rst	2
1		sm	1

Part 6: SP: Level seven subcarinal lymph nodes [REDACTED]

Block	Sect.	Site	PCs
3		BLN	3

Part 7: SP: Right level eleven interlobar lymph nodes [REDACTED]

Block	Sect.	Site	PCs
4		BLN	8

Part 8: SP: Right lower lobe lung [REDACTED]

Block	Sect.	Site	PCs
1		bm	1
3		pbn	3
4		rs	4
2		rsb	2
3		rst	3
1		sm	1
2		twb	2
1		vm	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample

** Continued on next page **

[page 6 of 6]
----- Page 6 of 6
examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS BENIGN LYMPH NODE [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS BENIGN LYMPH NODES [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS BENIGN LYMPH NODES [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 4) FROZEN SECTION DIAGNOSIS BENIGN LYMPH NODE [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 5) FROZEN SECTION DIAGNOSIS INFILTRATING SQUAMOUS CELL CARCINOMA
[REDACTED]
PERMANENT DIAGNOSIS:
[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file 9892a1ba-1af0-4b48-a3c4-d21883b1a3d1 (TCGA-39-5028.3E8D3FAB-2418-4860-8119-A011528F2F06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).